Surgical pathology report (de-identified scan), TCGA case TCGA-61-2094, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2094-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LEFT ADNEXA, LEFT SALPINGO OOPHORECTOMY -

- A. HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA OF LEFT OVARY.
- B. PARATUBAL CYST.
- C. LEFT FALLOPIAN TUBE, UNREMARKABLE.

PART 2: RIGHT ADNEXA, RIGHT SALPINGO OOPHORECTOMY -

- A. HIGH GRADE POORLY DIFFERENTIATED SEROUS PAPILLARY CARCINOMA OF RIGHT OVARY, WITH FOCAL SURFACE INVOLVEMENT, ARISING IN SEROUS TUMOR OF LOW MALIGNANT POTENTIAL.
- B. RIGHT FALLOPIAN TUBE UNREMARKABLE.

PART 3: UTERUS WITHOUT BILATERAL ADNEXA (60 GM), TOTAL ABDOMINAL HYSTERECTOMY -

- A. CHRONIC CERVICITIS, FOCAL SQUAMOUS METAPLASIA, ENDOCERVICAL POLYP AND NABOTHIAN CYSTS.
- B. INACTIVE ENDOMETRIUM WITH FOCAL COMPLEX ATYPICAL HYPERPLASIA.
- C. ADENOMYOSIS.
- D. LEIOMYOMAS, UP TO 2.0 CM.

PART 4: SIGMOID, BIOPSY -

METASTATIC SEROUS PAPILLARY CARCINOMA.

PART 5: POSTERIOR CUL DE SAC, BIOPSY -

METASTATIC SEROUS PAPILLARY CARCINOMA.

PART 6: LEFT COMMON ILIAC LYMPH NODES, DISSECTION -

ONE REACTIVE LYMPH NODE FREE OF TUMOR (0/1).

PART 7: LEFT INTERNAL AND EXTERNAL ILIAC LYMPH NODES, DISSECTION -

SEVEN LYMPH NODES FREE OF TUMOR (0/7).

PART 8: LEFT OBTURATOR LYMPH NODES, DISSECTION -

TWO LYMPH NODES FREE OF TUMOR (0/3).

PART 9: RIGHT COMMON LYMPH NODES, DISSECTION -

TWO LYMPH NODES FREE OF TUMOR (0/2).

PART 10: RIGHT INTERNAL AND EXTERNAL ILIAC LYMPH NODES, DISSECTION -

THREE LYMPH NODES FREE OF TUMOR (0/3).

PART 11: RIGHT OBTURATOR LYMPH NODES, DISSECTION -

TWO LYMPH NODES FREE OF TUMOR (0/3).

PART 12: ANTERIOR CUL DE SAC, BIOPSY -

BENIGN FIBROADIPOSE TISSUE.

PART 13: RIGHT PELVIC, BIOPSY -

BENIGN FIBROADIPOSE TISSUE.

PART 14: LEFT CUL DE SAC, BIOPSY -

BENIGN FIBROADIPOSE TISSUE.

PART 15: LEFT GUTTER, BIOPSY -

BENIGN FIBROADIPOSE TISSUE.

PART 16: APPENDIX, APPENDECTOMY -

APPENDIX WITH FIBROUS OBLITERATION AND BENIGN EPITHELIAL INCLUSION.

PART 17: RIGHT PERIAORTIC LYMPH NODES, DISSECTION -

THREE LYMPH NODES FREE OF TUMOR (0/3).

PART 18: LEFT PERIAORTIC LYMPH NODES, DISSECTION -

FIVE LYMPH NODES FREE OF TUMOR (0/5).

PART 19: OMENTUM, EXCISION -

BENIGN ADIPOSE TISSUE.

PART 20: SIGMOID NODULE, EXCISION -

Source: NCI Genomic Data Commons file 5a213e8d-2780-4776-b8d1-a5791831322c (TCGA-61-2094.205B0520-854C-480E-881D-89BC8CBCFF75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).